MMRF case MMRF_2083 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eb12e341-b691-4a77-ba46-0b009e19f9e9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 870 days (2.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,404 days); ISS stage: I; Days to last known disease status: 870 days (2.4 years); Days to last follow up: 870 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 321 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 476 days (1.3 years); Days to treatment end: 630 days (1.7 years).
   Treatment given: Therapeutic agents: Daratumumab + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 659 days (1.8 years); Days to treatment end: 667 days (1.8 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Doxorubicin + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 682 days (1.9 years); Days to treatment end: 722 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 682 days (1.9 years); Days to treatment end: 683 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 804 days (2.2 years); Days to treatment end: 869 days (2.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 870.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Beta 2 Microglobulin 2.66 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 9.2 g/dL; Glucose 6.99 mmol/L.
- Day 57 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Beta 2 Microglobulin 2.24 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 6.16 mmol/L.
- Day 155 (ECOG 1): M Protein 1.5 g/dL; Beta 2 Microglobulin 2.45 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.5 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 9.68 mmol/L.
- Day 251 (ECOG 1): Hemoglobin 6.94 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 8.1 g/dL; Glucose 7.54 mmol/L.
- Day 327 (ECOG 1): M Protein 1.8 g/dL; Hemoglobin 6.94 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 8.53 mmol/L.
- Day 441: M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Beta 2 Microglobulin 2.32 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 8.2 g/dL; Glucose 9.19 mmol/L.
- Day 525 (ECOG 1): M Protein 1.9 g/dL; Beta 2 Microglobulin 2.45 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.7 g/dL; Glucose 8.2 mmol/L.
- Day 595 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 28.7 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 3.54 µg/mL.
- Day 797 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 23.8 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 5.21 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 8.2 g/dL; Glucose 8.25 mmol/L.

Other clinical attributes
- Day -23: Weight: 104 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lymphoma; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_2083_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_2083_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
- Sample MMRF_2083_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 327 days.
